Somatic mutation profile of tumor specimen TARGET-10-PARFIH-09A (aliquot TARGET-10-PARFIH-09A-01D) from TARGET case TARGET-10-PARFIH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.3 years (1,925 days).
Specimen TARGET-10-PARFIH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc74d5f5-ecba-4768-af08-58d13f7f4785.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARFIH-14A (Bone Marrow Normal), aliquot TARGET-10-PARFIH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8f4ed3b-77c1-4f86-8cdd-2eec3b398d68

The open-access MAF lists 15 somatic variants for this specimen: 6 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 3, Intron 2, Nonsense Mutation 1, In Frame Ins 1, 3'Flank 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1086+1G>A p.X362_splice | Splice Site (SNP) | VAF 61/154 reads (40%) | catalogued as COSV50528851; called by muse, mutect2, varscan2
- GMPPB | c.761T>C p.V254A | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV57540281; called by muse, mutect2, varscan2
- LYST | c.6078C>A p.Y2026* | Nonsense Mutation (SNP) | VAF 9/55 reads (16%) | catalogued as rs80338660, CM021561, COSV67707063, COSV67714717; called by muse, mutect2, varscan2
- NOTCH1 | c.4777_4778insCAAGAATCC p.F1592_L1593insPRI | In Frame Ins (INS) | VAF 13/30 reads (43%) | catalogued as COSV53025183, COSV53025197; called by mutect2, pindel, varscan2
- RNF150 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.386); catalogued as COSV60800299; called by muse, mutect2, varscan2
- TEK | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 51/54 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764254208, COSV66235140; called by muse, mutect2, varscan2
- ANKRD10 | c.132G>A p.Q44= | Silent (SNP) | VAF 11/16 reads (69%) | called by muse, mutect2, varscan2
- DISP3 | c.160C>A p.R54= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV53829632; called by muse, mutect2, varscan2
- MAP2K7 | c.825G>A p.T275= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs373957718; called by muse, mutect2, varscan2
- OR4K17 | c.867G>T p.L289= | Silent (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- PAQR5 | c.78C>T p.F26= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as rs367787380; called by muse, mutect2, varscan2
- CPEB4 | c.1259-70G>A | Intron (SNP) | VAF 37/66 reads (56%) | called by muse, mutect2, varscan2
- CST9L | c.*128T>C | 3'UTR (SNP) | VAF 11/17 reads (65%) | called by muse, varscan2
- ELOF1 | c.188-99C>T | Intron (SNP) | VAF 12/137 reads (9%) | called by muse, mutect2
- IGHV3-20 | chr14:106210935 ins CGGGGGA | 3'Flank (INS) | VAF 22/74 reads (30%) | called by mutect2, pindel, varscan2
